Somatic mutation profile of tumor specimen 0DGL6N from CCDI case PBBSYF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.7 years (5,383 days).
Specimen 0DGL6N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf352ec2-b653-49a1-8c58-094e8419a219.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGL6O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b99811ad-af63-40b3-8e90-4f877f27f527

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, 3'UTR 2, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASKIN2 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 140/646 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375409576; called by muse, mutect2, varscan2
- CASR | c.2573C>T p.P858L (on ENST00000490131; = p.P935L on NM_000388.4) | Missense Mutation (SNP) | VAF 233/489 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs201950717, COSV56134409; called by muse, mutect2, varscan2
- DLG2 | c.1932C>G p.F644L | Missense Mutation (SNP) | VAF 55/1712 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV54636376, COSV99720783; called by muse, mutect2
- DNMT1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 326/1331 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs201749864, COSV100533287; called by muse, mutect2, varscan2
- DSCAML1 | c.3643C>T p.R1215W (on ENST00000321322; = p.R1155W on NM_020693.4) | Missense Mutation (SNP) | VAF 22/610 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs1358475816, COSV100356506; called by muse, mutect2
- IDO1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 306/640 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs187334376; called by muse, mutect2, varscan2
- IER3IP1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 124/535 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV56505444; called by muse, mutect2, varscan2
- LYST | c.11354G>A p.R3785H | Missense Mutation (SNP) | VAF 377/1308 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs370173269; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH11Y | c.2569G>A p.V857I (on ENST00000400457 / NM_032973.2; = p.V846I on NM_032971.3) | Missense Mutation (SNP) | VAF 296/480 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs777010130, COSV53075849; called by muse, mutect2, varscan2
- UBE3B | c.2507A>G p.Y836C | Missense Mutation (SNP) | VAF 204/753 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs763834013, COSV61073234; called by muse, mutect2, varscan2
- UMODL1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 512/829 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs756749467, COSV68578469; called by muse, mutect2, varscan2
- ZNF516 | c.3415G>A p.A1139T | Missense Mutation (SNP) | VAF 228/1220 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs752191224; called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 68/1448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- ITGB4 | c.3735G>T p.E1245D | Missense Mutation (SNP) | VAF 46/1529 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR8B3 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 413/485 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PRDM2 | c.3433T>C p.S1145P | Missense Mutation (SNP) | VAF 324/1341 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SND1 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 607/1786 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 110/2658 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ZPBP2 | c.842G>C p.G281A (on ENST00000348931 / NM_199321.3; = p.G259A on NM_198844.3) | Missense Mutation (SNP) | VAF 322/1736 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AC004997.1 | c.1035G>A p.R345= | Silent (SNP) | VAF 196/843 reads (23%) | called by muse, mutect2, varscan2
- CFAP61 | c.2211T>G p.V737= | Silent (SNP) | VAF 370/1156 reads (32%) | called by muse, mutect2, varscan2
- DSCC1 | c.706T>C p.L236= | Silent (SNP) | VAF 228/583 reads (39%) | catalogued as rs778462063; called by muse, mutect2, varscan2
- HELB | c.1962T>C p.H654= | Silent (SNP) | VAF 368/1370 reads (27%) | called by muse, mutect2, varscan2
- LYST | c.11355C>T p.R3785= | Silent (SNP) | VAF 384/1351 reads (28%) | catalogued as rs150849914; called by muse, mutect2, varscan2
- NLRP3 | c.3036A>T p.T1012= | Silent (SNP) | VAF 403/1298 reads (31%) | called by muse, mutect2, varscan2
- ZNF160 | c.783A>G p.E261= | Silent (SNP) | VAF 38/1417 reads (3%) | called by muse, mutect2
- ZNF268 | c.1815T>A p.T605= | Silent (SNP) | VAF 227/930 reads (24%) | called by muse, mutect2, varscan2
- MLLT10 | c.240+18030G>T | Intron (SNP) | VAF 224/507 reads (44%) | called by muse, mutect2, varscan2
- SPANXB1 | c.*32G>A | 3'UTR (SNP) | VAF 146/370 reads (39%) | called by muse, mutect2, varscan2
- TMEM88 | c.*101G>T | 3'UTR (SNP) | VAF 217/695 reads (31%) | called by muse, mutect2, varscan2
